Somatic mutation profile of tumor specimen TCGA-ZH-A8Y4-01A (aliquot TCGA-ZH-A8Y4-01A-11D-A417-09) from TCGA case TCGA-ZH-A8Y4, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 58.9 years (21,503 days).
Specimen TCGA-ZH-A8Y4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a836c35-5740-4af5-bf03-a38ade3ee4a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y4-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y4-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c56ee13-1990-4ecb-865f-1a1f764e0fd3

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Frame Shift Ins 3, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 1, Intron 1, Splice Site 1, 3'UTR 1, RNA 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAF | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 46/56 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV51691227, COSV51692413; called by muse, varscan2
- B3GNT6 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100845801; called by muse, mutect2, varscan2
- CLCN6 | c.1993C>G p.L665V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV56739240; called by muse, mutect2
- CTCFL | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs572527047, COSV54773442; called by muse, mutect2, varscan2
- DOCK2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748633577, COSV56948191; called by muse, mutect2
- NFKBIZ | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV58199754; called by muse, mutect2, varscan2
- PBRM1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV56262370; called by muse, mutect2, varscan2
- PF4V1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); catalogued as COSV99896276; called by muse, mutect2, varscan2
- PLXNA4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as rs765087543; called by muse, mutect2, varscan2
- PTH1R | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1375868219; called by muse, mutect2, varscan2
- SERPINE2 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51457543; called by muse, mutect2, varscan2
- TRAT1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as rs148894492; called by muse, mutect2, varscan2
- UPRT | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs1308060743, COSV64912443; called by muse, mutect2, varscan2
- ZNF234 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs910731020, COSV70604378; called by muse, mutect2, varscan2
- ZSCAN1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs1362867658; called by muse, mutect2, varscan2
- BAP1 | c.1823del p.D608Afs*9 | Frame Shift Del (DEL) | VAF 15/25 reads (60%) | called by mutect2, pindel, varscan2
- C18orf54 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CARD10 | c.1550A>G p.N517S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CYP2D6 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM3 | c.1013A>G p.Q338R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- HADHB | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1B | c.2755G>T p.G919* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- MROH5 | c.342C>A p.N114K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MVP | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2
- NOL12 | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PATJ | c.704C>A p.T235K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PRKCD | c.676A>C p.N226H | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RBFA | c.559A>C p.N187H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM25 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD2 | c.6035dup p.L2013Pfs*20 | Frame Shift Ins (INS) | VAF 30/63 reads (48%) | called by mutect2, pindel, varscan2
- SLC25A33 | c.709dup p.M237Nfs*8 | Frame Shift Ins (INS) | VAF 22/44 reads (50%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.809_814del p.Y270_F271del | In Frame Del (DEL) | VAF 36/79 reads (46%) | called by mutect2, pindel, varscan2
- SLIT2 | c.1832T>C p.L611S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMURF1 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.102); called by muse, mutect2
- TK2 | c.261dup p.V88Cfs*6 (on ENST00000299697; = p.V144Cfs*6 on NM_004614.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- TMEM141 | c.122-4_166del p.X41_splice | Splice Site (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- TYK2 | c.2387_2394del p.D796Gfs*12 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- Z83844.2 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 104/164 reads (63%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC15 | c.-8_22del | Translation Start Site (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ZNF407 | c.6721_6722del p.E2241Kfs*33 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by pindel, varscan2
- ZNF786 | c.581A>C p.E194A | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZYX | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ABCA7 | c.3024G>A p.V1008= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54030696; called by muse, mutect2, varscan2
- LRCH2 | c.2118A>G p.A706= | Silent (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- MRGPRE | c.876C>T p.D292= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs373696773; called by muse, varscan2
- OR8B3 | c.388T>C p.L130= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as rs758875017; called by muse, mutect2, varscan2
- PNCK | c.639C>T p.Y213= (on ENST00000340888 / NM_001366975.1; = p.Y296= on NM_001039582.3) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs782094866, COSV61742505; called by muse, mutect2, varscan2
- PXDN | c.1317T>C p.P439= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- SNX20 | c.675C>T p.A225= | Silent (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- THPO | c.750C>T p.L250= (on ENST00000649095 / NM_001290003.1; = p.L110= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.315T>C p.L105= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as rs1213090359; called by muse, mutect2, varscan2
- CD300LD | chr17:74592535 G>C | 5'Flank (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1778C>T | RNA (SNP) | VAF 42/168 reads (25%) | catalogued as rs777337847; called by muse, mutect2, varscan2
- RPL7A | c.415+75T>C | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*1G>A | 3'UTR (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
